Somatic mutation profile of tumor specimen HCM-CSHL-0376-D37-31A (aliquot HCM-CSHL-0376-D37-31A-11D-A78T-36) from HCMI case HCM-CSHL-0376-D37, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubulovillous adenoma, NOS; Tissue or organ of origin: Colon, NOS; Age at diagnosis: 75.4 years (27,551 days).
Specimen HCM-CSHL-0376-D37-31A: Sample type: Neoplasms of Uncertain and Unknown Behavior; Tissue type: Tumor; Tumor descriptor: Premalignant; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d12b1e7c-5b01-4cac-9617-793a04ec4596.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0376-D37-10A (Blood Derived Normal), aliquot HCM-CSHL-0376-D37-10A-01D-A78T-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c669c20c-8e42-42ff-9659-19b2a2d75cb7

The open-access MAF lists 150 somatic variants for this specimen: 97 protein-altering or splice-affecting, 35 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 82, Silent 35, Intron 10, Nonsense Mutation 7, 3'UTR 3, Frame Shift Del 3, 5'UTR 2, Frame Shift Ins 2, 3'Flank 2, Splice Region 2, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1495C>T p.R499* | Nonsense Mutation (SNP) | VAF 91/281 reads (32%) | hotspot (GDC flag); catalogued as rs137854580, CM930023, COSV57322064; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.2524G>A p.V842I | Missense Mutation (SNP) | VAF 95/245 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1057519738, COSV104371920, COSV54062791; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1513C>T p.R505C (on ENST00000281708 / NM_001349798.2; = p.R425C on NM_018315.5) | Missense Mutation (SNP) | VAF 161/367 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GAA | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 86/261 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs528367092, CM082741; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 145/313 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACSM4 | c.1021C>T p.R341W | Missense Mutation (SNP) | VAF 173/358 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs755148242, COSV68067243; called by muse, mutect2, varscan2
- ADCY2 | c.2894G>A p.R965Q | Missense Mutation (SNP) | VAF 76/165 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.435); catalogued as COSV57872898; called by muse, mutect2, varscan2
- ADGRL4 | c.1882G>A p.G628S | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV100875948, COSV66064393; called by muse, mutect2, varscan2
- AHNAK2 | c.7321G>A p.D2441N | Missense Mutation (SNP) | VAF 21/432 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.9); catalogued as rs377766612, COSV60915030; called by muse, mutect2
- ANKS1B | c.1619G>A p.R540Q | Missense Mutation (SNP) | VAF 82/302 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.953); catalogued as rs778044550, COSV61351807; called by muse, mutect2, varscan2
- APC | c.4334del p.T1445Kfs*28 | Frame Shift Del (DEL) | VAF 40/129 reads (31%) | catalogued as COSV57341535, COSV57358206; called by mutect2, pindel, varscan2
- ATP13A1 | c.2594G>A p.G865D | Missense Mutation (SNP) | VAF 95/286 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs866967026; called by muse, mutect2, varscan2
- CACNB4 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 62/174 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1023200310, COSV52390628; called by muse, mutect2, varscan2
- CAPN2 | c.1418A>G p.N473S | Missense Mutation (SNP) | VAF 188/532 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.06); catalogued as rs1194586307; called by muse, mutect2, varscan2
- CD5L | c.154G>A p.G52S | Missense Mutation (SNP) | VAF 72/358 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.791); catalogued as rs765807105, COSV63820985, COSV63823341; called by muse, mutect2, varscan2
- COL6A6 | c.3149C>T p.P1050L | Missense Mutation (SNP) | VAF 91/280 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as rs368734825, COSV100649980; called by muse, mutect2, varscan2
- CYP4F12 | c.1496G>A p.R499H | Missense Mutation (SNP) | VAF 84/201 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.296); catalogued as rs200958722; called by muse, mutect2, varscan2
- DACT3 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs1242335369; called by muse, mutect2, varscan2
- DENND2B | c.1118G>A p.R373Q | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT tolerated (0.59); PolyPhen benign (0.017); catalogued as COSV58205655; called by muse, mutect2, varscan2
- DNA2 | c.1361C>A p.S454* | Nonsense Mutation (SNP) | VAF 38/89 reads (43%) | catalogued as rs773154182; called by muse, mutect2, varscan2
- DOCK10 | c.6475G>A p.G2159R | Missense Mutation (SNP) | VAF 51/257 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as rs776649363, COSV99292230; called by muse, mutect2, varscan2
- ECSIT | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs758391824; called by muse, mutect2, varscan2
- F3 | c.305C>T p.T102M | Missense Mutation (SNP) | VAF 122/318 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs371434099; called by muse, mutect2, varscan2
- GAB4 | c.1034C>T p.T345M | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.183); catalogued as rs762931159, COSV101271901; called by muse, mutect2, varscan2
- HMGB2 | c.296+1G>A p.X99_splice | Splice Site (SNP) | VAF 28/79 reads (35%) | catalogued as rs112661861, COSV104408759; called by muse, mutect2, varscan2
- HOXB2 | c.365C>T p.P122L | Missense Mutation (SNP) | VAF 49/252 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs777610889; called by muse, mutect2, varscan2
- IGF1R | c.835C>T p.R279C | Missense Mutation (SNP) | VAF 175/450 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.695); catalogued as rs1567180721; called by muse, mutect2, varscan2
- KCNA6 | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 148/474 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746236187; called by muse, varscan2
- LCOR | c.2989G>A p.E997K | Missense Mutation (SNP) | VAF 76/203 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0.021); catalogued as rs778351999, COSV53714581; called by muse, mutect2, varscan2
- LEFTY2 | c.196C>T p.R66W | Missense Mutation (SNP) | VAF 134/330 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as rs370436460; called by muse, mutect2, varscan2
- LGI3 | c.1298G>A p.R433H | Missense Mutation (SNP) | VAF 143/317 reads (45%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.806); catalogued as rs113893603; called by muse, mutect2, varscan2
- LILRB3 | c.1109C>G p.S370* | Nonsense Mutation (SNP) | VAF 125/537 reads (23%) | catalogued as COSV99558015; called by muse, mutect2, varscan2
- LMF1 | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs573828508, COSV51895546; called by muse, mutect2
- LRFN4 | c.1177G>A p.A393T | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.89); PolyPhen benign (0.015); catalogued as rs767216993; called by muse, mutect2, varscan2
- LRP5 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 130/371 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs780921829, COSV53714391; called by muse, mutect2, varscan2
- MAP1B | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0.208); catalogued as COSV57097455; called by muse, mutect2, varscan2
- MMP21 | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1232442341; called by muse, mutect2
- MPP2 | c.1441C>T p.R481* (on ENST00000461854 / NM_001278372.2; = p.R457* on NM_005374.5) | Nonsense Mutation (SNP) | VAF 46/142 reads (32%) | catalogued as rs754463406, COSV52235759; called by muse, mutect2, varscan2
- MTA1 | c.1375G>T p.G459W | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100495395; called by muse, mutect2, varscan2
- MUC4 | c.6059C>G p.T2020S | Missense Mutation (SNP) | VAF 116/1250 reads (9%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.301); catalogued as rs1375442773; called by muse, mutect2
- NR2E3 | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 14/385 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1278777318; called by muse, mutect2
- NTNG2 | c.526G>A p.G176S | Missense Mutation (SNP) | VAF 148/375 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as rs531966081; called by muse, mutect2, varscan2
- NYAP1 | c.863C>T p.P288L | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.801); catalogued as rs574707021, COSV55720687; called by muse, mutect2, varscan2
- OBSL1 | c.4240C>T p.R1414C | Missense Mutation (SNP) | VAF 111/393 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as rs763912596; called by muse, mutect2, varscan2
- PHF8 | c.2225A>G p.Y742C (on ENST00000357988 / NM_001184896.1; = p.Y706C on NM_015107.3) | Missense Mutation (SNP) | VAF 173/243 reads (71%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.707); catalogued as rs782680617; called by muse, mutect2, varscan2
- PLCL1 | c.1597T>A p.L533I | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV70868140; called by muse, mutect2, varscan2
- PLXNA2 | c.85G>C p.A29P | Missense Mutation (SNP) | VAF 18/298 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as rs1157906080, COSV100885324; called by muse, mutect2
- PLXND1 | c.2419C>T p.R807C | Missense Mutation (SNP) | VAF 76/204 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.153); catalogued as rs200217905; called by muse, mutect2, varscan2
- PPFIBP2 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 121/368 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as rs561555393; called by muse, mutect2, varscan2
- RCL1 | c.1047A>T p.E349D | Missense Mutation (SNP) | VAF 17/218 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs371229350; called by muse, mutect2
- RREB1 | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 73/166 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs372987331; called by muse, mutect2, varscan2
- SIGLEC6 | c.527C>T p.T176M | Missense Mutation (SNP) | VAF 141/380 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.958); catalogued as rs780557269, COSV58431654; called by muse, mutect2, varscan2
- SPICE1 | c.34C>T p.R12* | Nonsense Mutation (SNP) | VAF 38/237 reads (16%) | catalogued as rs187457377, COSV55621016, COSV99871443; called by muse, mutect2, varscan2
- SPTBN2 | c.4438C>T p.R1480C | Missense Mutation (SNP) | VAF 135/402 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs113974204, COSV59447719; called by muse, mutect2, varscan2
- ST8SIA6 | c.753dup p.A252Sfs*40 | Frame Shift Ins (INS) | VAF 27/97 reads (28%) | catalogued as rs758746672; called by mutect2, varscan2
- SYTL5 | c.1369C>T p.R457W | Missense Mutation (SNP) | VAF 66/91 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375053219; called by muse, mutect2, varscan2
- TCF15 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 84/197 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.858); catalogued as rs952836687; called by muse, mutect2, varscan2
- TRPS1 | c.628C>G p.P210A (on ENST00000220888 / NM_001330599.2; = p.P223A on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 86/224 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.006); catalogued as COSV99634282; called by muse, mutect2, varscan2
- UNC5CL | c.1333C>T p.R445W | Missense Mutation (SNP) | VAF 75/175 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs147879961; called by muse, mutect2, varscan2
- WNT4 | c.647A>C p.E216A | Missense Mutation (SNP) | VAF 55/154 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as CM042504; called by muse, mutect2, varscan2
- ZFHX4 | c.8000C>T p.A2667V | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.719); catalogued as rs775966431, COSV50478678; called by muse, mutect2, varscan2
- ZNF735 | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 69/275 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs773098060, COSV70034667; called by muse, mutect2, varscan2
- CHEK2 | c.721+6A>G | Splice Region (SNP) | VAF 60/210 reads (29%) | called by muse, mutect2, varscan2
- DNAH17 | c.10552G>A p.E3518K | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- DNAH5 | c.12095T>G p.L4032W | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- EGFLAM | c.2381C>A p.A794D | Missense Mutation (SNP) | VAF 51/177 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- EPRS1 | c.1001_1004dup p.C336Vfs*9 | Frame Shift Ins (INS) | VAF 61/172 reads (35%) | called by mutect2, varscan2
- FAM71E2 | c.811+5G>T | Splice Region (SNP) | VAF 13/47 reads (28%) | called by mutect2, varscan2
- FRG2C | c.547A>C p.M183L | Missense Mutation (SNP) | VAF 56/722 reads (8%) | SIFT tolerated (0.88); PolyPhen benign (0.01); called by muse, mutect2
- FSIP2 | c.8614A>G p.K2872E | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2
- GIMAP6 | c.321G>T p.E107D | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- GPR20 | c.721C>A p.Q241K | Missense Mutation (SNP) | VAF 11/259 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); called by muse, mutect2
- GRM7 | c.1960G>T p.V654L | Missense Mutation (SNP) | VAF 84/228 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- MSI1 | c.350C>T p.S117L | Missense Mutation (SNP) | VAF 72/318 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- MYBPC3 | c.1355C>T p.P452L | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- NOS2 | c.2381G>T p.G794V | Missense Mutation (SNP) | VAF 70/177 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- NPAS1 | c.1691C>T p.A564V | Missense Mutation (SNP) | VAF 77/194 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCDHB4 | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 320/984 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, varscan2
- PIGZ | c.1297G>T p.G433W | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBM10 | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 27/280 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- RPL23A | c.332A>G p.Q111R | Missense Mutation (SNP) | VAF 12/364 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.208); called by muse, mutect2
- SCART1 | c.2846A>T p.Y949F | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SETDB1 | c.1096del p.R366Efs*9 | Frame Shift Del (DEL) | VAF 95/332 reads (29%) | called by mutect2, pindel, varscan2
- SLC23A3 | c.1101del p.L368Cfs*31 | Frame Shift Del (DEL) | VAF 119/399 reads (30%) | called by mutect2, pindel, varscan2
- SLITRK4 | c.2090G>T p.S697I | Missense Mutation (SNP) | VAF 76/100 reads (76%) | SIFT deleterious (0); PolyPhen benign (0.317); called by muse, mutect2, varscan2
- SPTBN4 | c.6766G>A p.D2256N | Missense Mutation (SNP) | VAF 117/356 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- TBC1D22A | c.883C>T p.Q295* | Nonsense Mutation (SNP) | VAF 96/296 reads (32%) | called by muse, mutect2, varscan2
- TENM4 | c.7094C>T p.T2365I | Missense Mutation (SNP) | VAF 26/284 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- THBS2 | c.1840C>A p.Q614K | Missense Mutation (SNP) | VAF 43/213 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TNRC6B | c.1927G>T p.E643* | Nonsense Mutation (SNP) | VAF 67/201 reads (33%) | called by muse, mutect2, varscan2
- TTN | c.15708G>T p.Q5236H (on ENST00000591111; = p.Q4309H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/45 reads (33%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- USP17L7 | c.1446G>T p.Q482H | Missense Mutation (SNP) | VAF 213/588 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- VCL | c.992T>G p.M331R | Missense Mutation (SNP) | VAF 39/541 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.116); called by muse, mutect2
- WNT3 | c.364G>A p.G122S | Missense Mutation (SNP) | VAF 75/174 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF184 | c.1024G>C p.A342P | Missense Mutation (SNP) | VAF 38/204 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ZNF780B | c.781A>T p.S261C | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.924); called by muse, mutect2
- ZNF880 | c.323T>C p.L108P | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.233); called by muse, varscan2
- ABCA8 | c.2541T>C p.Y847= | Silent (SNP) | VAF 35/96 reads (36%) | catalogued as COSV52193980; called by muse, mutect2, varscan2
- AC100868.1 | c.1944C>G p.P648= | Silent (SNP) | VAF 94/213 reads (44%) | called by muse, mutect2, varscan2
- ADGRL3 | c.3906C>A p.V1302= | Silent (SNP) | VAF 38/106 reads (36%) | called by muse, mutect2, varscan2
- ALPK3 | c.2649G>A p.P883= | Silent (SNP) | VAF 117/337 reads (35%) | catalogued as rs115903792; ClinVar: likely benign; called by muse, mutect2, varscan2
- ANO7 | c.2559C>T p.F853= (on ENST00000274979; = p.F799= on NM_001370694.2) | Silent (SNP) | VAF 99/286 reads (35%) | catalogued as rs146725594; called by muse, mutect2, varscan2
- ARID3A | c.441C>T p.Y147= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as rs867742749; called by muse, mutect2, varscan2
- ATXN7 | c.1242G>A p.P414= | Silent (SNP) | VAF 61/157 reads (39%) | catalogued as rs190142927, COSV55748385; called by muse, mutect2, varscan2
- BASP1 | c.309G>A p.A103= | Silent (SNP) | VAF 3/29 reads (10%) | called by muse, mutect2
- CDK13 | c.3738G>A p.T1246= | Silent (SNP) | VAF 63/148 reads (43%) | catalogued as rs1281030407; called by muse, mutect2, varscan2
- CELSR2 | c.3900C>T p.H1300= | Silent (SNP) | VAF 15/216 reads (7%) | catalogued as rs1294486832, COSV54770676; called by muse, mutect2
- CFAP299 | c.258T>A p.A86= | Silent (SNP) | VAF 18/143 reads (13%) | called by muse, mutect2, varscan2
- CFAP299 | c.531A>G p.Q177= | Silent (SNP) | VAF 39/123 reads (32%) | called by muse, mutect2, varscan2
- COL25A1 | c.105C>T p.A35= | Silent (SNP) | VAF 73/248 reads (29%) | catalogued as COSV101211269; called by muse, mutect2, varscan2
- CUTA | c.225C>T p.C75= (on ENST00000488034 / NM_001014840.2; = p.C52= on NM_015921.3) | Silent (SNP) | VAF 83/192 reads (43%) | catalogued as rs781064898; called by muse, mutect2, varscan2
- DNAH2 | c.2844C>T p.N948= | Silent (SNP) | VAF 70/179 reads (39%) | catalogued as rs753977609; called by muse, mutect2, varscan2
- DSCAML1 | c.4581C>T p.S1527= (on ENST00000321322; = p.S1467= on NM_020693.4) | Silent (SNP) | VAF 29/78 reads (37%) | catalogued as rs760599656; called by muse, mutect2, varscan2
- DSP | c.6360C>T p.T2120= | Silent (SNP) | VAF 120/347 reads (35%) | catalogued as rs374252141; ClinVar: likely benign; called by muse, mutect2, varscan2
- DST | c.5451G>A p.Q1817= | Silent (SNP) | VAF 62/175 reads (35%) | catalogued as rs767818989; called by muse, mutect2, varscan2
- ELMO1 | c.510A>T p.I170= | Silent (SNP) | VAF 58/149 reads (39%) | called by muse, mutect2, varscan2
- ERICH3 | c.2433G>C p.A811= | Silent (SNP) | VAF 22/54 reads (41%) | called by muse, mutect2, varscan2
- FAM186B | c.1083G>A p.P361= | Silent (SNP) | VAF 26/103 reads (25%) | catalogued as COSV57723915; called by muse, mutect2, varscan2
- FCSK | c.1317C>T p.L439= | Silent (SNP) | VAF 69/154 reads (45%) | catalogued as rs752329812; called by muse, mutect2, varscan2
- GPR153 | c.519C>T p.G173= | Silent (SNP) | VAF 198/567 reads (35%) | catalogued as rs1159801931; called by muse, mutect2, varscan2
- ITGA11 | c.495C>T p.I165= | Silent (SNP) | VAF 44/110 reads (40%) | catalogued as rs770568289, COSV59883000; called by muse, mutect2, varscan2
- LTBP4 | c.789G>T p.A263= (on ENST00000308370 / NM_001042544.1; = p.A226= on NM_003573.2) | Silent (SNP) | VAF 164/436 reads (38%) | called by muse, mutect2, varscan2
- MEP1A | c.1447A>C p.R483= | Silent (SNP) | VAF 82/382 reads (21%) | called by muse, mutect2, varscan2
- PAX2 | c.123C>T p.I41= | Silent (SNP) | VAF 52/101 reads (51%) | catalogued as rs771654993; called by muse, mutect2, varscan2
- PCDHA1 | c.1863G>A p.P621= | Silent (SNP) | VAF 18/483 reads (4%) | catalogued as COSV65375111; called by muse, mutect2
- PLXNB1 | c.2502C>T p.S834= | Silent (SNP) | VAF 23/88 reads (26%) | catalogued as rs528799252; called by muse, mutect2
- PRKCQ | c.69G>A p.E23= | Silent (SNP) | VAF 47/180 reads (26%) | called by muse, mutect2, varscan2
- RAD23A | c.555A>G p.R185= | Silent (SNP) | VAF 15/161 reads (9%) | called by muse, mutect2
- RBMXL3 | c.1872C>T p.Y624= | Silent (SNP) | VAF 215/333 reads (65%) | catalogued as rs193239868; called by muse, mutect2, varscan2
- RTL6 | c.597G>C p.V199= | Silent (SNP) | VAF 68/187 reads (36%) | called by muse, mutect2, varscan2
- TMOD3 | c.402C>T p.L134= | Silent (SNP) | VAF 66/179 reads (37%) | catalogued as rs774599943, COSV57943835; called by muse, mutect2, varscan2
- TSKS | c.774G>A p.P258= | Silent (SNP) | VAF 36/604 reads (6%) | catalogued as rs757213011; called by muse, mutect2
- AC139769.1 | n.214-4236C>T | Intron (SNP) | VAF 152/453 reads (34%) | catalogued as rs1212009246; called by muse, mutect2, varscan2
- ADGRE4P | n.2063-614C>T | Intron (SNP) | VAF 68/194 reads (35%) | called by muse, mutect2, varscan2
- AFF1 | c.1038+33A>G | Intron (SNP) | VAF 70/222 reads (32%) | catalogued as rs745563405; called by muse, varscan2
- CCDC65 | chr12:48925028 G>C | 3'Flank (SNP) | VAF 12/128 reads (9%) | called by muse, mutect2, varscan2
- CSF2RA | c.647-43G>A | Intron (SNP) | VAF 82/324 reads (25%) | called by muse, mutect2, varscan2
- FAM183BP | n.881C>T | RNA (SNP) | VAF 115/266 reads (43%) | catalogued as rs569780333; called by muse, mutect2, varscan2
- FUBP1 | c.*37G>A | 3'UTR (SNP) | VAF 41/105 reads (39%) | catalogued as COSV53929051; called by muse, mutect2, varscan2
- GFOD1 | c.253+16415C>T | Intron (SNP) | VAF 19/53 reads (36%) | called by muse, mutect2
- GPR161 | c.-18C>T | 5'UTR (SNP) | VAF 44/102 reads (43%) | catalogued as rs1383560797; called by muse, mutect2, varscan2
- GRIA2 | c.2292-236G>A | Intron (SNP) | VAF 15/153 reads (10%) | called by muse, mutect2
- H3C11 | c.-2C>T | 5'UTR (SNP) | VAF 56/159 reads (35%) | catalogued as rs187255691; called by muse, mutect2, varscan2
- HSPD1 | c.427+71A>C | Intron (SNP) | VAF 49/114 reads (43%) | called by muse, varscan2
- LCP2 | c.188+17C>T | Intron (SNP) | VAF 84/213 reads (39%) | called by muse, mutect2, varscan2
- LIPN | c.535+28G>A | Intron (SNP) | VAF 88/252 reads (35%) | catalogued as rs1450579642; called by muse, mutect2, varscan2
- PPP1R1A | chr12:54577420 C>T | 3'Flank (SNP) | VAF 41/80 reads (51%) | called by muse, mutect2, varscan2
- TMED1 | c.*678dup | 3'UTR (INS) | VAF 77/212 reads (36%) | called by mutect2, varscan2
- TMED1 | c.*677delinsAA | 3'UTR (INS) | VAF 66/277 reads (24%) | called by mutect2*, pindel, varscan2*
- TMEM135 | c.510-18525G>T | Intron (SNP) | VAF 49/91 reads (54%) | called by muse, mutect2, varscan2
